Somatic mutation profile of tumor specimen TCGA-HT-7480-01A (aliquot TCGA-HT-7480-01A-11D-2086-08) from TCGA case TCGA-HT-7480, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 33.7 years (12,291 days).
Specimen TCGA-HT-7480-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b83ab245-fb51-42ed-b2e0-87931698d3dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7480-10A (Blood Derived Normal), aliquot TCGA-HT-7480-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a25fab9-a670-40d6-aab1-3fb2838c9f62

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/104 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM32 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1466724520, COSV65948649; called by mutect2, varscan2
- CHGB | c.1958A>G p.K653R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV66760226; called by muse, mutect2, varscan2
- CIC | c.3009-1G>T p.X1003_splice | Splice Site (SNP) | VAF 41/108 reads (38%) | catalogued as COSV50546992, COSV50560822; called by muse, mutect2, varscan2
- DCHS1 | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1332143389, COSV55034350; called by muse, mutect2, varscan2
- DNAH11 | c.8806C>G p.P2936A | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as COSV60952563; called by muse, mutect2, varscan2
- ENPP3 | c.2227del p.V743* | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as COSV100717659; called by mutect2, pindel, varscan2
- FBH1 | c.685G>T p.V229L (on ENST00000362091 / NM_178150.3; = p.V280L on NM_032807.4) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV62982330; called by muse, mutect2, varscan2
- FOXD4 | c.229A>C p.S77R | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58699736; called by muse, mutect2, varscan2
- KRT37 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746964284, COSV56657761; called by muse, mutect2, varscan2
- MAX | c.293A>C p.Q98P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV52416569; called by muse, mutect2, varscan2
- MUC5B | c.11593G>A p.V3865M | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs375778294; called by muse, mutect2, varscan2
- MYH8 | c.4268G>A p.R1423Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs768767249, COSV101238087, COSV67963633; called by muse, mutect2, varscan2
- PDGFA | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1266496019, COSV63279554; called by muse, mutect2
- RIDA | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54704574; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | PolyPhen benign (0.007); catalogued as COSV50074112; called by muse, mutect2, varscan2
- SUPT6H | c.3560C>T p.A1187V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV58925427; called by muse, mutect2, varscan2
- TLR9 | c.2951G>T p.R984L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62346470; called by muse, mutect2, varscan2
- USP14 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55280463; called by muse, mutect2, varscan2
- ZNF91 | c.3304G>A p.G1102R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs370911694; called by muse, mutect2, varscan2
- AFTPH | c.527del p.P176Lfs*7 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- ETAA1 | c.1586C>A p.S529Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.525); called by muse, mutect2
- CD244 | c.579C>T p.G193= (on ENST00000368033 / NM_001166663.2; = p.G188= on NM_016382.4) | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as COSV59237321; called by muse, mutect2, varscan2
- KCNG1 | c.63C>T p.D21= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs768778949, COSV65368073; called by muse, mutect2, varscan2
- LATS2 | c.3036C>T p.N1012= | Silent (SNP) | VAF 55/214 reads (26%) | catalogued as rs530420148, COSV66874617; called by muse, mutect2, varscan2
- OR4K2 | c.828C>A p.T276= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as COSV53849200, COSV53851413; called by muse, mutect2, varscan2
- PIGO | c.693C>T p.F231= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV53053413; called by mutect2, varscan2
- SLC26A9 | c.1032C>T p.S344= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV61602248; called by muse, mutect2, varscan2
